Somatic mutation profile of tumor specimen TCGA-N5-A4RD-01A (aliquot TCGA-N5-A4RD-01A-11D-A28R-08) from TCGA case TCGA-N5-A4RD, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IVB; Age at diagnosis: 69.6 years (25,413 days).
Specimen TCGA-N5-A4RD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c69ca7cc-e59d-4914-9d23-6a950fb8f360.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N5-A4RD-10A (Blood Derived Normal), aliquot TCGA-N5-A4RD-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d01f6fc3-70fb-496d-8d7f-5712af37c250

The open-access MAF lists 58 somatic variants for this specimen: 49 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 8, Nonsense Mutation 3, Frame Shift Ins 3, Frame Shift Del 2, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 24/27 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CHD4 | c.3274C>T p.R1092W (on ENST00000357008 / NM_001363606.2; = p.R1105W on NM_001273.5) | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58898720; called by muse, mutect2, varscan2
- CSMD3 | c.2249C>T p.T750M (on ENST00000297405 / NM_001363185.1; = p.T646M on NM_052900.3) | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1490537303, COSV52337134, COSV99820895; called by muse, mutect2, varscan2
- DEF6 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs1377306273; called by muse, mutect2, varscan2
- EBF1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.764); catalogued as rs1442881041, COSV58189295; called by muse, mutect2, varscan2
- EPHB1 | c.594C>A p.S198R | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.99); catalogued as rs778514646, COSV67662455; called by muse, mutect2, varscan2
- FRMPD1 | c.3580C>T p.Q1194* | Nonsense Mutation (SNP) | VAF 23/91 reads (25%) | catalogued as rs754292389, COSV66699320; called by muse, mutect2, varscan2
- GINS2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as rs1340414927, COSV99497989; called by muse, mutect2, varscan2
- GPR37 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767810765, COSV58259947; called by muse, mutect2, varscan2
- H3C6 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as rs1377708081, COSV64519609, COSV64519990; called by muse, mutect2, varscan2
- HELB | c.2836C>T p.R946C | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs774433175, COSV56072110; called by muse, mutect2, varscan2
- IL36G | c.104G>T p.W35L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as COSV52078565; called by muse, mutect2, varscan2
- KMT2D | c.7018C>T p.P2340S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as rs1297761342; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LY6G5B | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs563595765, COSV65497889; called by muse, mutect2, varscan2
- MLLT1 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 120/138 reads (87%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs767911025, COSV53129959, COSV53130123; called by muse, mutect2, varscan2
- PATJ | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as rs1460961918; called by muse, varscan2
- PCLO | c.10555C>G p.Q3519E | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs1453590213, COSV61623695; called by muse, mutect2, varscan2
- PNMA3 | c.1261G>A p.G421S | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); catalogued as COSV104427212; called by muse, mutect2, varscan2
- TMEM132E | c.2159G>A p.R720Q (on ENST00000321639; = p.R810Q on NM_001304438.2) | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs374583943, COSV58694836; called by muse, mutect2, varscan2
- TRPC1 | c.2113C>T p.H705Y (on ENST00000476941 / NM_001251845.2; = p.H671Y on NM_003304.4) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.838); catalogued as COSV56429234; called by muse, mutect2, varscan2
- VPS50 | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.993); catalogued as rs1378535430; called by muse, mutect2, varscan2
- C1QL2 | c.706C>A p.Q236K | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- CNOT6 | c.1297_1298del p.N433Sfs*5 | Frame Shift Del (DEL) | VAF 21/47 reads (45%) | called by mutect2, pindel, varscan2
- EYA4 | c.1496A>G p.N499S (on ENST00000531901 / NM_001301013.1; = p.N493S on NM_004100.5) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GLB1L3 | c.1034C>G p.T345S | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- H2AC20 | c.10_11insA p.R4Qfs*108 | Frame Shift Ins (INS) | VAF 59/149 reads (40%) | called by muse*, mutect2, varscan2*
- H2AC20 | c.14del p.G5Afs*24 | Frame Shift Del (DEL) | VAF 63/154 reads (41%) | called by muse*, mutect2, varscan2*
- HEPHL1 | c.878A>T p.H293L | Missense Mutation (SNP) | VAF 53/64 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HMCN1 | c.14948C>T p.S4983F | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- HOXC13 | c.669G>C p.W223C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- KLHL1 | c.1758G>T p.M586I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGALS7 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by mutect2, varscan2
- LSG1 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- NLGN1 | c.2350A>T p.I784F | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHF7 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 47/56 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PIK3R1 | c.1902dup p.E635* (on ENST00000521381 / NM_181523.3; = p.E365* on NM_181504.4) | Frame Shift Ins (INS) | VAF 35/87 reads (40%) | called by mutect2, pindel, varscan2
- PRICKLE3 | c.1166C>A p.A389D | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- PTPRG | c.3391C>T p.Q1131* | Nonsense Mutation (SNP) | VAF 27/36 reads (75%) | called by muse, mutect2, varscan2
- RPRD2 | c.1763A>G p.K588R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SPTBN1 | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TELO2 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 78/147 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TIAL1 | c.611dup p.N204Kfs*48 | Frame Shift Ins (INS) | VAF 38/102 reads (37%) | called by mutect2, pindel, varscan2
- TNFRSF6B | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.61); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TRIM2 | c.1592_1600dup p.L533_Q534insRQL (on ENST00000437508; = p.L560_Q561insRQL on NM_015271.5 and 4 other RefSeq transcripts) | In Frame Ins (INS) | VAF 11/56 reads (20%) | called by mutect2, varscan2
- UBXN1 | c.556C>G p.Q186E | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZFHX3 | c.1813C>A p.P605T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2
- ZNF572 | c.612T>G p.I204M | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.088); called by muse, mutect2
- BAK1 | c.564C>T p.I188= | Silent (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- H2AC20 | c.12T>G p.R4= | Silent (SNP) | VAF 49/135 reads (36%) | called by muse, varscan2
- LDB2 | c.90C>T p.Y30= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV58782822; called by muse, mutect2, varscan2
- PDIA3 | c.291C>T p.V97= | Silent (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- RECQL5 | c.183C>T p.C61= | Silent (SNP) | VAF 88/185 reads (48%) | catalogued as rs1418811110; called by muse, mutect2, varscan2
- SNX25 | c.1668T>C p.F556= | Silent (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- TPCN2 | c.2016C>T p.I672= | Silent (SNP) | VAF 33/42 reads (79%) | called by muse, mutect2, varscan2
- ZNF333 | c.438T>A p.A146= | Silent (SNP) | VAF 38/45 reads (84%) | catalogued as COSV52887819; called by muse, mutect2, varscan2
- ADRA1A | c.*2A>G | 3'UTR (SNP) | VAF 81/185 reads (44%) | called by muse, mutect2, varscan2
